Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANS, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AANS-01A (Primary Tumor).

[page 1 of 3]
Acc#:

Ord #=

RESULTED

Collect D/T=

SURGICAL PATHOL

Modifiers:

(1 of 1)

Surgical Pathology Report

Specimen(s) Received
Left testicle

Clinical History
Not stated.

*ICD-O-3
Mixed germ cell tumor 9085/3
Site @ Testis NOS C62.9
JAS 3/31/14*

Gross Description

Left testicle: Received fresh from the OR is a 160-gm testicle measuring 18 x 6.5 x 4 cm. The testicle portion measures 7 x 6.5 x 4 cm. The spermatic cord measures 0.5 cm in length x 1.1 cm in diameter. On sectioning the testicle parenchyma is replaced by solid tumor which shows a variegated appearance measuring 5.6 x 4.7 x 2.6 cm. A portion of fresh tumor is taken for research study. The tumor appears to be focally attached to but is limited to the tunica albuginea. Representative sections are submitted as follows:

- 1 spermatic cord margin
- 2-9 representative section of tumor and testis

Date of Dictation:

Gross Description By:

Microscopic Description
Performed.

Final Pathologic Diagnosis

Left testicle: Mixed germ cell tumor, embryonal carcinoma (90%) and seminoma (10%).

- Tumor size 5.6 cm, limited to the testicle.
- Tunica vaginalis not involved.
- Intertubular germ cell neoplasia present.

[page 2 of 3]
(Continued)

Acct#:

-Lymphovascular invasion present.
-No direct tumor invasion at surgical margin, but shows
lymphovascular spread at the margin.

Comment: Deeper sections examined on slide 7.

Pathologic Stage: T1NXMX (Stage I)

Attending Pathologist:

***Electronically Signed Out By

**

Patient Name:
Case #:
Med. Rec. #:
Location:
Date Collected:

PW TSS dx discrepancy form, TCGA
tumor is: embryonal 50%
adenoma 50%

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Embryonal Carcinoma 90% Seminoma 10%	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Embryonal Carcinoma 50% Seminoma 50%	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	histologic heterogeneity characteristic of mixed germ cell tumors.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file afc01365-bdec-405d-9a10-d60ec33eb449 (TCGA-XE-AANS-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).